Somatic mutation profile of tumor specimen HCM-CSHL-0621-C18-06A (aliquot HCM-CSHL-0621-C18-06A-11D-A881-36) from HCMI case HCM-CSHL-0621-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 72.0 years (26,307 days).
Specimen HCM-CSHL-0621-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77beb5d4-8b16-4284-a600-6bd61ed747d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0621-C18-11A (Solid Tissue Normal), aliquot HCM-CSHL-0621-C18-11A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1400fef8-f392-41ae-8df6-e4e31df8debd

The open-access MAF lists 125 somatic variants for this specimen: 96 protein-altering or splice-affecting, 24 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 24, Splice Region 4, Nonsense Mutation 4, 3'UTR 3, Frame Shift Del 2, Intron 2, Frame Shift Ins 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 112/456 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.4219G>A p.V1407I | Missense Mutation (SNP) | VAF 128/423 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.052); catalogued as rs747329081; called by muse, mutect2, varscan2
- AMN | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 94/359 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as rs748210579; called by muse, mutect2, varscan2
- AOAH | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 139/447 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202089348, COSV51742780; called by muse, mutect2, varscan2
- CACNA1H | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 268/750 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as rs371658961; called by muse, mutect2, varscan2
- CAMK4 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 183/323 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs374581815, COSV56670305; called by muse, mutect2, varscan2
- CCDC7 | c.2261T>G p.L754R | Missense Mutation (SNP) | VAF 68/219 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1203648180; called by muse, mutect2, varscan2
- CDH17 | c.2095C>T p.R699W | Missense Mutation (SNP) | VAF 144/452 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs764816423, COSV50325787; called by muse, mutect2
- CNTN1 | c.1230G>A p.A410= | Splice Region (SNP) | VAF 103/295 reads (35%) | catalogued as rs144896071; called by muse, mutect2, varscan2
- CRACD | c.2108G>A p.C703Y | Missense Mutation (SNP) | VAF 163/511 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.633); catalogued as rs1166805601, COSV51723387; called by muse, mutect2, varscan2
- CYLC1 | c.72C>A p.S24R | Missense Mutation (SNP) | VAF 65/108 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as rs1355978822; called by muse, mutect2, varscan2
- DNAH5 | c.11987G>A p.R3996H | Missense Mutation (SNP) | VAF 134/389 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as rs768677731; called by muse, mutect2, varscan2
- EGFLAM | c.1113C>A p.C371* | Nonsense Mutation (SNP) | VAF 112/342 reads (33%) | catalogued as COSV59294353; called by muse, mutect2, varscan2
- ESRRB | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 146/398 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as rs948871827; called by muse, mutect2, varscan2
- FLT4 | c.2552T>C p.L851P | Missense Mutation (SNP) | VAF 117/425 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99987093; called by muse, mutect2, varscan2
- HOOK2 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 130/425 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1455714684, COSV53402078; called by muse, mutect2, varscan2
- HOXC13 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 252/863 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV54500516; called by muse, mutect2, varscan2
- HOXD3 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 161/580 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747637499, COSV50879425, COSV99980406; called by muse, mutect2, varscan2
- IL10RA | c.1507G>T p.E503* | Nonsense Mutation (SNP) | VAF 150/542 reads (28%) | catalogued as COSV57140704; called by mutect2, varscan2
- KLRB1 | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 117/353 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99987374; called by muse, mutect2, varscan2
- KRT76 | c.1621A>G p.S541G | Missense Mutation (SNP) | VAF 257/929 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs372674456; called by muse, mutect2, varscan2
- LLGL2 | c.2794C>T p.R932W | Missense Mutation (SNP) | VAF 167/535 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs757256244, COSV51343539; called by muse, mutect2, varscan2
- MEGF11 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 192/384 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs750210212; called by muse, mutect2, varscan2
- MKI67 | c.5181G>A p.M1727I | Missense Mutation (SNP) | VAF 389/627 reads (62%) | SIFT tolerated (0.26); PolyPhen benign (0.164); catalogued as COSV64077564; called by muse, mutect2, varscan2
- MMP16 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 128/394 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV54152643; called by muse, mutect2, varscan2
- NBN | c.39A>G p.G13= | Splice Region (SNP) | VAF 93/300 reads (31%) | catalogued as rs876660470; ClinVar: likely benign; called by muse, mutect2, varscan2
- NCOA1 | c.3045A>C p.K1015N | Missense Mutation (SNP) | VAF 151/545 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as COSV56050803; called by muse, mutect2, varscan2
- PASD1 | c.1636C>T p.R546W | Missense Mutation (SNP) | VAF 267/427 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.363); catalogued as rs144296185, COSV64854173; called by muse, mutect2, varscan2
- PCDHB14 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 142/490 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.879); catalogued as rs782298964, COSV53391073, COSV53391754; called by muse, mutect2, varscan2
- PCDHGA12 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 171/592 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1433790348, COSV104383019; called by muse, mutect2, varscan2
- PDE6A | c.2319A>C p.Q773H | Missense Mutation (SNP) | VAF 99/288 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99678029; called by muse, mutect2, varscan2
- PDZRN4 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 142/500 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs990836428; called by muse, varscan2
- PIK3C2A | c.3766A>G p.I1256V | Missense Mutation (SNP) | VAF 22/490 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1438700912, COSV56406120; called by muse, mutect2
- PKHD1 | c.9749C>T p.S3250L | Missense Mutation (SNP) | VAF 186/531 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV61879162; called by muse, mutect2, varscan2
- RANBP10 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 134/420 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58162007; called by muse, varscan2
- SCARA5 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 168/458 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs774080674, COSV100108129; called by muse, mutect2, varscan2
- SCART1 | c.1417C>T p.R473W | Missense Mutation (SNP) | VAF 53/983 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1266745276; called by muse, mutect2
- SCN5A | c.2436G>A p.L812= | Splice Region (SNP) | VAF 119/322 reads (37%) | catalogued as COSV100351284; called by muse, mutect2, varscan2
- SEMA3G | c.2324C>T p.T775M | Missense Mutation (SNP) | VAF 171/595 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.711); catalogued as rs759858543, COSV51594128; called by muse, mutect2, varscan2
- SETBP1 | c.4023A>C p.K1341N | Missense Mutation (SNP) | VAF 111/268 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV56321377; called by muse, mutect2, varscan2
- SPATA31A3 | c.2242G>A p.V748M | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1468994246; called by mutect2, varscan2
- SPEG | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 267/798 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV56667786; called by muse, mutect2, varscan2
- STARD8 | c.2377G>A p.A793T | Missense Mutation (SNP) | VAF 202/317 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as rs373291071; called by muse, mutect2, varscan2
- SYNE1 | c.15082G>A p.A5028T (on ENST00000367255 / NM_182961.4; = p.A4957T on NM_033071.3) | Missense Mutation (SNP) | VAF 126/443 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as rs748882675, COSV104375152; called by muse, mutect2, varscan2
- TMEM132C | c.2797G>T p.V933L | Missense Mutation (SNP) | VAF 202/619 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59419281; called by muse, mutect2, varscan2
- TNR | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 270/987 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs371035988, COSV54876906; called by muse, mutect2, varscan2
- TSHZ2 | c.625T>G p.F209V | Missense Mutation (SNP) | VAF 160/682 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61591215; called by muse, mutect2, varscan2
- UNC80 | c.5893G>A p.V1965M | Missense Mutation (SNP) | VAF 119/393 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs746218899; called by muse, mutect2, varscan2
- WDR62 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 90/268 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159993236; called by muse, mutect2
- ZFP42 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 112/299 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs746841063, COSV100479168; called by muse, mutect2, varscan2
- ZNF385D | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 102/377 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768839606, COSV55756041, COSV99876109; called by muse, mutect2, varscan2
- ZNF879 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 130/440 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1390862090; called by muse, mutect2, varscan2
- ABCB9 | c.431C>A p.T144N | Missense Mutation (SNP) | VAF 163/659 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- APC | c.4009_4034del p.L1337Ifs*8 | Frame Shift Del (DEL) | VAF 221/424 reads (52%) | called by mutect2, pindel, varscan2
- ARHGDIB | c.461A>C p.E154A | Missense Mutation (SNP) | VAF 127/452 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ARHGEF5 | c.2649A>T p.Q883H | Missense Mutation (SNP) | VAF 121/526 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- ATP5MC1 | c.226A>C p.T76P | Missense Mutation (SNP) | VAF 12/436 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- BCL9L | c.834+1G>T p.X278_splice | Splice Site (SNP) | VAF 293/460 reads (64%) | called by muse, mutect2, varscan2
- BRINP3 | c.982A>G p.K328E | Missense Mutation (SNP) | VAF 138/291 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CAT | c.1154A>C p.N385T | Missense Mutation (SNP) | VAF 138/412 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.686); called by mutect2, varscan2
- CLIC5 | c.1190A>C p.E397A (on ENST00000185206 / NM_001370649.1; = p.E238A on NM_016929.5) | Missense Mutation (SNP) | VAF 136/457 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- COL22A1 | c.3362C>T p.P1121L | Missense Mutation (SNP) | VAF 150/513 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- CRYBG1 | c.5644C>T p.H1882Y | Missense Mutation (SNP) | VAF 119/443 reads (27%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- DACT1 | c.2174A>C p.E725A | Missense Mutation (SNP) | VAF 213/698 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DHX38 | c.2696A>C p.K899T | Missense Mutation (SNP) | VAF 214/629 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOXP1 | c.454del p.E152Nfs*54 | Frame Shift Del (DEL) | VAF 134/437 reads (31%) | called by mutect2, pindel, varscan2
- FSHR | c.157T>G p.F53V | Missense Mutation (SNP) | VAF 97/282 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- FSIP2 | c.11497T>G p.L3833V | Missense Mutation (SNP) | VAF 123/366 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GRIK5 | c.612G>T p.K204N | Missense Mutation (SNP) | VAF 160/537 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- H3-3A | c.119_121del p.H40del | In Frame Del (DEL) | VAF 55/302 reads (18%) | called by mutect2, pindel, varscan2
- IFT81 | c.1358dup p.I455Yfs*5 | Frame Shift Ins (INS) | VAF 48/207 reads (23%) | called by mutect2, pindel, varscan2
- IGKV1-9 | c.44T>G p.L15R | Missense Mutation (SNP) | VAF 132/538 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IGKV1-9 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 133/539 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- IGLON5 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 181/568 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL6R | c.1065A>G p.P355= | Splice Region (SNP) | VAF 81/251 reads (32%) | called by muse, mutect2, varscan2
- LMBR1 | c.1427C>A p.S476* | Nonsense Mutation (SNP) | VAF 126/404 reads (31%) | called by muse, varscan2
- LOXL2 | c.138G>T p.Q46H | Missense Mutation (SNP) | VAF 182/377 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MLXIPL | c.707A>C p.E236A | Missense Mutation (SNP) | VAF 212/679 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MMP14 | c.1241A>C p.K414T | Missense Mutation (SNP) | VAF 158/522 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- MYCBP2 | c.6366A>C p.K2122N (on ENST00000357337; = p.K2160N on NM_015057.5) | Missense Mutation (SNP) | VAF 130/403 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- NUDT12 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 90/276 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- RUNDC3A | c.1198G>A p.G400R | Missense Mutation (SNP) | VAF 112/393 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC9C2 | c.68A>G p.D23G | Missense Mutation (SNP) | VAF 97/490 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SLFN14 | c.518T>G p.L173R | Missense Mutation (SNP) | VAF 136/440 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- SSH2 | c.1361A>C p.N454T | Missense Mutation (SNP) | VAF 92/308 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- STAT5A | c.1724A>G p.D575G | Missense Mutation (SNP) | VAF 147/506 reads (29%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- SVOP | c.282_282+1insCTTCG p.M95Lfs*9 | Frame Shift Ins (INS) | VAF 51/248 reads (21%) | called by pindel, varscan2
- SVOP | c.275T>A p.L92* | Nonsense Mutation (SNP) | VAF 78/283 reads (28%) | called by muse, varscan2
- TAF1 | c.1256C>T p.S419F (on ENST00000373790 / NM_138923.4; = p.S440F on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 134/218 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- TENM3 | c.1373A>G p.E458G | Missense Mutation (SNP) | VAF 197/584 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TGM7 | c.610T>C p.Y204H | Missense Mutation (SNP) | VAF 120/397 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- THOC3 | c.913C>A p.Q305K | Missense Mutation (SNP) | VAF 50/319 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOP3B | c.2194G>A p.G732R | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- TOP3B | c.50T>A p.I17N | Missense Mutation (SNP) | VAF 97/326 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by mutect2, varscan2
- WHRN | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 297/902 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ZNF721 | c.888A>T p.E296D (on ENST00000338977; = p.E308D on NM_133474.4) | Missense Mutation (SNP) | VAF 160/411 reads (39%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ANO5 | c.1722C>T p.Y574= | Silent (SNP) | VAF 122/396 reads (31%) | catalogued as rs781145099, COSV61084440, COSV61090655; ClinVar: likely benign; called by muse, mutect2, varscan2
- APOB | c.9321C>T p.N3107= | Silent (SNP) | VAF 195/574 reads (34%) | catalogued as rs72653101, COSV51936637; called by muse, mutect2, varscan2
- ATP1A4 | c.1914C>T p.G638= | Silent (SNP) | VAF 152/475 reads (32%) | catalogued as rs1446256557; called by muse, mutect2, varscan2
- ATP4A | c.331C>T p.L111= | Silent (SNP) | VAF 189/643 reads (29%) | called by muse, mutect2, varscan2
- CDH11 | c.1794C>T p.N598= | Silent (SNP) | VAF 211/752 reads (28%) | catalogued as rs563299959, COSV51764281, COSV51767424; called by muse, mutect2, varscan2
- COL19A1 | c.333C>T p.N111= | Silent (SNP) | VAF 102/315 reads (32%) | catalogued as rs143252227; called by muse, mutect2, varscan2
- COL20A1 | c.2571G>A p.A857= | Silent (SNP) | VAF 173/721 reads (24%) | catalogued as rs1170886302; called by muse, mutect2, varscan2
- COL22A1 | c.237C>T p.V79= | Silent (SNP) | VAF 228/731 reads (31%) | catalogued as rs752433406, COSV104407814; called by muse, mutect2, varscan2
- DOK7 | c.174G>A p.T58= | Silent (SNP) | VAF 153/579 reads (26%) | catalogued as COSV100403213, COSV60772701; called by muse, mutect2, varscan2
- GBX1 | c.24C>T p.S8= | Silent (SNP) | VAF 143/522 reads (27%) | called by muse, mutect2, varscan2
- ITGAX | c.750C>T p.A250= | Silent (SNP) | VAF 96/362 reads (27%) | catalogued as rs775201614; called by muse, mutect2, varscan2
- JAML | c.390G>A p.A130= (on ENST00000356289 / NM_001098526.2; = p.A120= on NM_153206.3) | Silent (SNP) | VAF 95/377 reads (25%) | catalogued as rs774361136; called by muse, mutect2, varscan2
- KLF15 | c.1089G>A p.S363= | Silent (SNP) | VAF 110/358 reads (31%) | catalogued as rs1197313656; called by muse, varscan2
- NRXN2 | c.624C>T p.P208= | Silent (SNP) | VAF 211/470 reads (45%) | called by muse, mutect2, varscan2
- PCDH7 | c.6G>A p.L2= | Silent (SNP) | VAF 168/586 reads (29%) | called by muse, mutect2, varscan2
- PDZD4 | c.1635C>T p.R545= | Silent (SNP) | VAF 320/472 reads (68%) | catalogued as rs1361920534; called by muse, varscan2
- SI | c.5328G>A p.G1776= | Silent (SNP) | VAF 101/374 reads (27%) | catalogued as rs1020747413; called by muse, mutect2, varscan2
- SLC16A13 | c.672C>T p.T224= | Silent (SNP) | VAF 189/665 reads (28%) | catalogued as COSV100338610; called by muse, mutect2, varscan2
- SLC9A4 | c.426C>T p.G142= | Silent (SNP) | VAF 220/780 reads (28%) | catalogued as rs575529823, COSV54828670, COSV54837751; called by muse, mutect2, varscan2
- SOX3 | c.654C>A p.L218= | Silent (SNP) | VAF 279/451 reads (62%) | called by muse, mutect2, varscan2
- SYCN | c.234C>T p.S78= | Silent (SNP) | VAF 207/588 reads (35%) | called by muse, mutect2, varscan2
- TM7SF3 | c.669G>A p.Q223= | Silent (SNP) | VAF 102/315 reads (32%) | called by muse, mutect2, varscan2
- TUBB1 | c.1059C>G p.V353= | Silent (SNP) | VAF 192/768 reads (25%) | called by muse, mutect2, varscan2
- TUBB4B | c.906C>T p.A302= | Silent (SNP) | VAF 134/478 reads (28%) | called by muse, mutect2, varscan2
- ARHGAP22 | c.989-209G>A | Intron (SNP) | VAF 229/810 reads (28%) | called by muse, mutect2, varscan2
- CCPG1 | c.*3091C>T | 3'UTR (SNP) | VAF 84/261 reads (32%) | called by muse, mutect2, varscan2
- GCNT1 | c.*1253_*1254insG | 3'UTR (INS) | VAF 94/393 reads (24%) | catalogued as rs990855328; called by pindel, varscan2
- PIDD1 | c.1303-136G>A | Intron (SNP) | VAF 148/446 reads (33%) | catalogued as rs574433149; called by muse, mutect2
- SLITRK4 | c.*295A>G | 3'UTR (SNP) | VAF 113/188 reads (60%) | called by muse, mutect2, varscan2
